Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A3PL, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A3PL-06A (Metastatic).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Malignant melanoma skin, NOS.

PROCEDURE: Excision mass (site).

SPECIFIC CLINICAL QUESTION: Not stated.

OUTSIDE TISSUE DIAGNOSIS: Not stated.

PRIOR MALIGNANCY: Skin cancer, melanoma.

CHEMORADIATION: Not stated.

ORGAN TRANSPLANT: Not stated.

IMMUNOSUPPRESSION: Not stated.

OTHER DISEASES: Back pain, diabetes type I.

Collection Date:

**FINAL DIAGNOSIS:****PARTS 1**

THROUGH 6: TUMOR OF SKIN AND SUBCUTANEOUS TISSUE OF RIGHT ARM, RIGHT POSTERIOR FLANK #1, RIGHT POSTERIOR FLANK #3, RIGHT POSTERIOR FLANK #3, ADDITIONAL RIGHT FLANK TISSUE AND RIGHT THIGH MASS, EXCISIONS -

- A. METASTATIC MELANOMA IN SKIN AND SUBCUTANEOUS TISSUE WITH FOCI OF ULCERATION AND EXTENSIVE VASCULAR PERMEATION SEEN (see comment).
- B. EXAMINED NEAREST INKED MARGINS VERY CLOSE.

COMMENT:

Immunostains reveal tumor to be positive for S100, Melan-A, and tyrosinase. Results of the immunostains confirm the above diagnosis. In part #1, foci of junctional nests are identified, however epidermotropism is common in metastatic melanoma and given the extent of tumor this likely represents metastases.

ICD-0-3

Melanoma, NOS 8720/3

Site: subcutaneous tissue, arm C49.1

TCGA specimen from (R) arm.

LW 3/8/12		

Source: NCI Genomic Data Commons file a1f25d4b-ddd3-4dfa-8794-421eeed841fe (TCGA-ER-A3PL.249C231D-FD24-4E23-87D3-11D844B41EBF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).